Gene-level copy-number profile of tumor specimen TCGA-AC-A6IX-01A from TCGA case TCGA-AC-A6IX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 49.2 years (17,969 days).
Specimen TCGA-AC-A6IX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.a96dcbf3-d86b-4747-810d-f6d9751d273e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A6IX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/201c989c-2cab-4386-ab72-681178d51a9c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 12,250; copy number 2: 43,801; copy number 3: 2,813; copy number 4: 62; copy number 5: 154; copy number 6: 303; copy number 7: 126; copy number 8: 12; copy number 9: 232; copy number 10: 29; copy number 12: 15; copy number 17: 7; copy number 18: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A6IX-01A-12D-A32H-01): tumor purity 0.5, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:109,002,465–109,037,967, 1 gene (within-gene range 0–1): AP003123.1.
- chr11:109,120,878–109,263,564, 2 genes: RNA5SP349, SNORD39.
- chr11:109,422,190–109,429,167, 1 gene: C11orf87.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 887 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–151,791,416, 337 genes, copy number 6–9 (within-gene range 3–9) (broad region; genes not listed).
- chr8:91,909,738–92,421,798, 8 genes, copy number 6: PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3.
- chr8:97,853,021–99,013,743, 30 genes, copy number 6: AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P, STK3, AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P, AP003467.1, AP003467.2, RPL19P14, AC016877.2, MRPL57P7, RN7SKP85, AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1.
- chr8:99,091,738–99,348,256, 5 genes, copy number 6: AC107909.2, AC107909.1, AP004290.1, AP004289.2, AP004289.1.
- chr8:100,157,906–100,259,278, 1 gene, copy number 7 (within-gene range 2–7): SPAG1.
- chr8:100,185,138–101,492,499, 43 genes, copy number 7–9 (within-gene range 3–9): Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3.
- chr8:104,590,733–107,498,055, 27 genes, copy number 10–18 (within-gene range 2–18): ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1.
- chr8:109,240,919–124,539,458, 167 genes, copy number 6–17 (broad region; genes not listed).
- chr11:58,579,063–61,969,490, 150 genes, copy number 5 (broad region; genes not listed).
- chr11:68,312,591–71,252,577, 68 genes, copy number 7 (broad region; genes not listed).
- chr11:76,186,325–77,314,032, 28 genes, copy number 6: WNT11, AP000785.1, LINC02761, THAP12, GVQW3, Y_RNA, AP002360.1, EMSY, AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1.
- chr11:86,791,059–87,025,777, 10 genes, copy number 8: PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8.
- chr11:87,094,734–87,121,596, 2 genes, copy number 8: XIAPP2, AP002967.1.
- chr11:87,480,736–87,721,233, 7 genes, copy number 6: AP003497.1, AP003497.2, AP001784.1, RNU6-1135P, U6, LINC02711, AP000756.1.
- chr16:70,802,084–71,230,722, 4 genes, copy number 5 (within-gene range 1–5): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.

Autosomal genes at a single copy (total copy number 1): 9,829. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
